MMRF case MMRF_2473 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/f938c66f-ed96-4e75-a8dd-0c50d983f82c

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 74 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 74.3 years (27,139 days); ISS stage: I; Days to last known disease status: 534 days (1.5 years); Days to last follow up: 534 days (1.5 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -9 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 62.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.85 mg/dL; Beta 2 Microglobulin 2.39 µg/mL; Hemoglobin 6.08 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 288 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.28 mmol/L; Albumin 35 g/L; Total Protein 6.1 g/dL; Glucose 5.72 mmol/L.
- Day 72 (ECOG 3): Serum Free Immunoglobulin Light Chain, Kappa 17.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.64 mg/dL; Beta 2 Microglobulin 2.4 µg/mL; Hemoglobin 5.64 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.15 mmol/L; Albumin 33 g/L; Total Protein 5.5 g/dL; Glucose 6.93 mmol/L.
- Day 174 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 9.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.34 mg/dL; Hemoglobin 5.77 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 248 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.03 mmol/L; Albumin 35 g/L; Total Protein 5.9 g/dL; Glucose 5.45 mmol/L.
- Day 258 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 11.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.51 mg/dL; Immunoglobulin G 9.49 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 3.29 µg/mL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 7.32 mmol/L.
- Day 343 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 23.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.62 mg/dL; Hemoglobin 6.63 mmol/L; Leukocytes 8.1 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 6.88 mmol/L.
- Day 453 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 20.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.92 mg/dL; Immunoglobulin G 7.3 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 2.94 µg/mL; Hemoglobin 5.33 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 1.73 mmol/L; Albumin 36 g/L; Total Protein 5.8 g/dL; Glucose 5.12 mmol/L.
- Day 534 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 23.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.89 mg/dL; Beta 2 Microglobulin 3.56 µg/mL; Hemoglobin 6.63 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 8.47 mmol/L.

Other clinical attributes
- Day -9: Weight: 78 kg; Height: 157 cm.

Biospecimens (2 samples)
- Sample MMRF_2473_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -9 days.
- Sample MMRF_2473_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -9 days.
